Somatic mutation profile of tumor specimen TCGA-FB-A78T-01A (aliquot TCGA-FB-A78T-01A-12D-A32N-08) from TCGA case TCGA-FB-A78T, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 71.7 years (26,179 days).
Specimen TCGA-FB-A78T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf2db31d-de1d-49df-b76c-ae28e6da112f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FB-A78T-10A (Blood Derived Normal), aliquot TCGA-FB-A78T-10A-01D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ddbeed6-05ab-4ccb-adb9-13fda8fc56eb

The open-access MAF lists 51 somatic variants for this specimen: 36 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 12, Nonsense Mutation 3, Intron 2, Frame Shift Del 1, In Frame Del 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 74/252 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCF3 | c.1876A>G p.M626V | Missense Mutation (SNP) | VAF 165/634 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.439); catalogued as COSV99491473; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1453C>T p.R485C | Missense Mutation (SNP) | VAF 169/802 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs375355414, COSV54996602; called by muse, mutect2, varscan2
- APBA2 | c.1567G>T p.A523S | Missense Mutation (SNP) | VAF 59/175 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101258166; called by muse, mutect2, varscan2
- ARHGAP31 | c.2075C>T p.P692L | Missense Mutation (SNP) | VAF 197/867 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as rs1420231956, COSV99957188; called by muse, mutect2, varscan2
- ATRNL1 | c.2721G>C p.M907I | Missense Mutation (SNP) | VAF 68/263 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV100370896; called by muse, mutect2, varscan2
- CLSTN2 | c.2459G>A p.R820Q | Missense Mutation (SNP) | VAF 122/497 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs560530846, COSV71722438; called by muse, mutect2, varscan2
- CR2 | c.722T>A p.F241Y | Missense Mutation (SNP) | VAF 18/362 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.53); catalogued as COSV100889652; called by muse, mutect2
- GARRE1 | c.2104G>T p.A702S | Missense Mutation (SNP) | VAF 80/389 reads (21%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.015); catalogued as rs780303216, COSV100209471; called by muse, mutect2, varscan2
- GLI1 | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 22/526 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1215799189, COSV57365554; called by muse, mutect2
- HAS1 | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 160/572 reads (28%) | catalogued as rs762776728, COSV99708426; called by muse, mutect2, varscan2
- IGHE | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs370977516; called by muse, mutect2, varscan2
- LNX2 | c.951G>C p.E317D | Missense Mutation (SNP) | VAF 80/369 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV100310729; called by muse, mutect2, varscan2
- MAGEB6 | c.1189G>C p.D397H | Missense Mutation (SNP) | VAF 209/613 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100983756; called by muse, mutect2, varscan2
- MANEAL | c.1366C>T p.L456F (on ENST00000373045 / NM_001113482.1; = p.L234F on NM_152496.2) | Missense Mutation (SNP) | VAF 40/324 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as rs1557575599, COSV100203923; called by muse, mutect2, varscan2
- MBIP | c.554_555insA p.I186Yfs*2 | Frame Shift Ins (INS) | VAF 21/116 reads (18%) | catalogued as COSV100576785; called by mutect2, pindel, varscan2
- NCOA6 | c.1405C>T p.Q469* | Nonsense Mutation (SNP) | VAF 163/621 reads (26%) | catalogued as COSV100750084; called by muse, mutect2, varscan2
- OBSCN | c.10825G>A p.V3609M | Missense Mutation (SNP) | VAF 151/653 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.521); catalogued as rs374049885, COSV52789522; called by muse, mutect2, varscan2
- PARP9 | c.856G>T p.A286S | Missense Mutation (SNP) | VAF 187/768 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV100831174; called by muse, mutect2, varscan2
- POLK | c.1309G>C p.E437Q | Missense Mutation (SNP) | VAF 26/504 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as COSV99605977; called by muse, mutect2
- PSMA1 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.144); catalogued as rs371834255, COSV67166223; called by muse, mutect2
- PTPRT | c.1640A>G p.N547S | Missense Mutation (SNP) | VAF 120/456 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.237); catalogued as COSV100627695; called by muse, mutect2, varscan2
- RIC1 | c.572A>G p.Q191R | Missense Mutation (SNP) | VAF 188/763 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV99317390; called by muse, mutect2, varscan2
- SLC5A2 | c.1519G>C p.G507R | Missense Mutation (SNP) | VAF 107/367 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV100393212; called by muse, mutect2, varscan2
- SMAD4 | c.1558G>T p.E520* | Nonsense Mutation (SNP) | VAF 131/353 reads (37%) | catalogued as CM1410464, COSV61685467; called by muse, mutect2, varscan2
- SRR | c.575G>C p.G192A | Missense Mutation (SNP) | VAF 24/308 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs141694122, COSV56786849; called by muse, mutect2
- STAG2 | c.752A>C p.E251A | Missense Mutation (SNP) | VAF 21/446 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99493659; called by muse, mutect2
- TMEM131 | c.5043C>A p.N1681K | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV99487897; called by muse, mutect2, varscan2
- TRHDE | c.1673A>C p.K558T | Missense Mutation (SNP) | VAF 13/210 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.119); catalogued as COSV99671024; called by muse, mutect2
- VSNL1 | c.165C>A p.F55L | Missense Mutation (SNP) | VAF 59/473 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99723109; called by muse, mutect2, varscan2
- ZC3H6 | c.3055G>A p.G1019R | Missense Mutation (SNP) | VAF 43/207 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs1462105382, COSV100674616; called by muse, mutect2, varscan2
- ZNF385D | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 50/214 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs571099747, COSV55752958; called by muse, mutect2, varscan2
- ZNF585A | c.1660G>A p.E554K (on ENST00000292841 / NM_001288800.2; = p.E499K on NM_152655.3) | Missense Mutation (SNP) | VAF 102/480 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.793); catalogued as rs572122130, COSV53062883; called by muse, mutect2, varscan2
- CDKN2A | c.206_215del p.E69Afs*74 | Frame Shift Del (DEL) | VAF 23/76 reads (30%) | called by mutect2, pindel
- MRC1 | c.4064G>C p.C1355S | Missense Mutation (SNP) | VAF 36/951 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPATA31E1 | c.378_380del p.L127del | In Frame Del (DEL) | VAF 50/278 reads (18%) | called by pindel, varscan2
- ARAP1 | c.3327G>C p.V1109= (on ENST00000393609 / NM_001040118.2; = p.V864= on NM_015242.4) | Silent (SNP) | VAF 11/118 reads (9%) | catalogued as COSV100501937; called by muse, mutect2
- ARHGAP36 | c.1515C>T p.S505= | Silent (SNP) | VAF 43/174 reads (25%) | catalogued as rs375497123, COSV52269551; called by muse, mutect2, varscan2
- DCAF12L1 | c.654G>A p.A218= | Silent (SNP) | VAF 85/311 reads (27%) | catalogued as COSV64421520; called by muse, varscan2
- FOXJ1 | c.342C>T p.Y114= | Silent (SNP) | VAF 69/257 reads (27%) | catalogued as rs200854622, COSV99487021; called by muse, mutect2, varscan2
- LMAN1L | c.471C>T p.D157= | Silent (SNP) | VAF 58/262 reads (22%) | catalogued as rs535407762, COSV100547719; called by muse, mutect2, varscan2
- MAS1L | c.336C>A p.I112= | Silent (SNP) | VAF 68/272 reads (25%) | catalogued as COSV101009689; called by muse, mutect2, varscan2
- NCAPH | c.1965G>A p.L655= | Silent (SNP) | VAF 19/385 reads (5%) | catalogued as rs1251919143, COSV99545868; called by muse, mutect2
- PIK3CG | c.897C>T p.N299= | Silent (SNP) | VAF 55/257 reads (21%) | catalogued as rs1220639059, COSV63247243, COSV63247651; called by muse, mutect2, varscan2
- PLIN4 | c.2088C>T p.V696= (on ENST00000301286; = p.V711= on NM_001367868.2) | Silent (SNP) | VAF 264/1959 reads (13%) | catalogued as rs780498744, COSV100013364; called by muse, mutect2, varscan2
- TOX2 | c.1359A>T p.P453= (on ENST00000358131 / NM_001098798.2; = p.P429= on NM_032883.3) | Silent (SNP) | VAF 36/800 reads (5%) | catalogued as rs1007786138, COSV100363923; called by muse, mutect2
- ZFHX3 | c.1728C>T p.G576= | Silent (SNP) | VAF 107/412 reads (26%) | catalogued as rs756457277, COSV51712479; called by muse, mutect2, varscan2
- ZNF546 | c.1380T>C p.H460= | Silent (SNP) | VAF 108/386 reads (28%) | catalogued as rs201944442, COSV100713458; called by muse, mutect2, varscan2
- CA6 | c.259+2053G>A | Intron (SNP) | VAF 27/165 reads (16%) | catalogued as COSV101077560; called by muse, mutect2, varscan2
- DLG3 | c.1145+669G>T | Intron (SNP) | VAF 16/159 reads (10%) | catalogued as COSV99529600; called by muse, mutect2
- MIR508 | n.38C>T | RNA (SNP) | VAF 45/128 reads (35%) | catalogued as rs1427077649; called by muse, mutect2, varscan2
